Surgical pathology report (de-identified scan), TCGA case TCGA-59-2355, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Roswell Park, specimen TCGA-59-2355-01A (Primary Tumor).

[page 1 of 5]
TCGA-59-2355

SURGICAL PATHOLOGY REPORT

*****Addendum*****

SPECIMEN(S): A. RIGHT ADNEXA
B. LEFT OVARY
C. UTERUS & CERVIX
D. ABDOMINAL TUMOR
E. OMENTUM

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Ovarian tumor

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA1, FSA2 (right adnexa): Poorly differentiated adenocarcinoma favor serous.

GROSS DESCRIPTION:

A. RIGHT ADNEXA

Received fresh for frozen section is a cystic ovarian mass measuring 11 x 11 x 4 cm. The surface of the specimen shows a multinodular mass measuring 5 x 4 x 4 cm. The remainder of the surface is tan-pink and smooth. The specimen is sectioned to show a multiloculated cyst filled with tan-yellow serous fluid. Sectioning through the multinodular tumor on top of the specimen shows a yellow, fleshy cut surface. The lining of the cyst is covered with papillary projections ranging from 0.1 cm up to 1 cm in length. The largest papillary projection is in the area corresponding to the multinodular tumor seen on the surface of the specimen. The attached

[page 2 of 5]
[REDACTED]

fallopian tube is 6 cm in length and 0.5 cm in diameter and is grossly unremarkable. Representative sections of the specimen are submitted as follows:

FSA1-FSA2: sections of the cyst and multinodular area for frozen section

A3-A4: sections of the thin area of the cyst wall

A5-A12: sections of the intracystic and surface nodular area

A13: sections of fallopian tube

B. LEFT OVARY

Received fixed in a container labeled with matching patient information and specimen identification is an ovarian mass with attached fallopian tube. The ovarian mass measures overall 4 x 3 x 2.5 cm. The surface of the ovary shows multiple multinodular tumors ranging from 0.9 to 2 cm in greatest dimension. The fimbrial end of the fallopian tube shows similar tumor nodule measuring 2 x 1.5 x 1 cm. The remainder of the fallopian tube measures 5 cm in length and 0.5 cm in diameter and is grossly unremarkable. Sectioning through the ovary shows tan-yellow, fleshy cut surface without obvious parenchymal nodules. Representative sections of the specimen are submitted as follows:

B1-B3: sections of ovary with attached surface tumor

B4: sections of fallopian tube and attached tumor

C. UTERUS AND CERVIX

Received fixed in a container labeled with matching patient information and specimen identification is a hysterectomy specimen consisting of uterus with attached cervix. The specimen weighs 138 grams. The uterus measures 8.5 x 7.5 x 4.5 cm. The external configuration of the uterus is slightly distorted by subserosal nodule located at the superior posterior aspect of the tumor. The peritoneal reflection at the anterior lower aspect of the tumor shows infiltration with tumor. The area infiltrated with tumor measures 5.5 x 2.5 x 1 cm. The exocervix is 3 x 2.5 cm and is covered by tan-pink unremarkable mucosa. The specimen is opened bilaterally and shows possible endometrial polypoid lesion. The largest is located at the fundus and measures 3.5 x 3 x 1.5 cm. The second polyp is seen at the endocervical canal, however, it is connected with a long stalk to the fundus. This polyp measures 6 cm from the base of the (at the fundus) to the tip and 1.5 x 1.5 at the tip. The third polyp is located at the anterior wall and measures 0.8 x 0.5 x 0.5 cm. Sectioning throughout the myometrium shows that the three polyps are confined to the endometrium without evidence of myometrial invasion. The myometrium also shows multiple subserosal and intramural tan-white nodules ranging between 0.5 and 1.3 cm in greatest dimension. The myometrium measures 2.5 cm at the anterior wall and 2 cm at the posterior wall. Sectioning through the reflection of the peritoneum where a tumor is seen shows no invasion into the myometrium. This tumor has tan-yellow, glistening cut surface. Representative sections of the specimen are submitted in thirteen cassettes as follows:

C1-C2: sections from the tip of the first (fundic) polyp

C3-C4: section of base of the first polyp with full thickness myometrium

C5: sections of tip of second polyp (long pedunculated polyp)

C6: sections of the base of second polyp with full thickness endometrium and myometrium

C7: sections of the third polyp at anterior wall

C8-C9: sections of tumor at anterior peritoneal reflection

C10: additional full thickness section of anterior endometrium and myometrium

[REDACTED]

[page 3 of 5]
Patient [REDACTED]
Specimen # [REDACTED]
Medical Record [REDACTED]

C11: sections of uterine nodule

C12: posterior cervix

C13: anterior cervix

D. ABDOMINAL TUMOR

Received fixed in a container labeled with matching patient information and specimen identification are two nodular pieces of tan soft tissue measuring 0.8 and 1.4 cm in greatest dimension. Each piece is bisected and submitted in toto in a separate cassette.

E. OMENTUM

Received are multiple fragments of tan-yellow focally hemorrhagic firm and nodular soft tissue ranging from 1 to 19 cm and measuring 19 x 8 x 2 cm in aggregate. Sectioning shows tan-white to yellow focally necrotic cut surface. Representative sections of the specimen are submitted in two cassettes (multiple sections per each cassette).

Note: Tissue procurement was performed on part A. Gross photographs are taken for parts A and C.

DIAGNOSIS:

A. OVARY AND FALLOPIAN TUBE, RIGHT, EXCISION:

- PAPILLARY SEROUS CYSTADENOCARCINOMA, POORLY DIFFERENTIATED (GRADE III).
- TUMOR SIZE 11 CM. SEE TEMPLATE.
- FALLOPIAN TUBE, NO TUMOR SEEN.

B. OVARY AND FALLOPIAN TUBE, LEFT, EXCISION:

- METASTATIC POORLY DIFFERENTIATED PAPILLARY SEROUS CARCINOMA INVOLVING OVARIAN SURFACE AND FALLOPIAN TUBE SEROSA.

C. UTERUS AND CERVIX, HYSTERECTOMY:

- METASTATIC PAPILLARY SEROUS CARCINOMA INVOLVING SEROSAL SURFACE OF UTERUS (5.5 x 2.5 x 1CM.) WITH LYMPHOVASCULAR INVASION
- BENIGN ENDOMETRIAL POLYPS (x3) IN A BACKGROUND OF CYSTIC ATROPHY OF ENDOMETRIUM.
- LEIOMYOMA OF UTERUS.
- ENDOMETRIOSIS.
- CERVIX WITH BENIGN ENDOCERVICAL POLYP.

D. SOFT TISSUE, ABDOMEN, EXCISION:

- METASTATIC, POORLY DIFFERENTIATED, PAPILLARY SEROUS CARCINOMA.

E. OMENTUM, EXCISION:

- METASTATIC, POORLY DIFFERENTIATED, PAPILLARY SEROUS CARCINOMA..

[page 4 of 5]
OVARIAN NEOPLASM TEMPLATE

Specimen type: TAH/BSO
Tumor site and size: Right 11 cm.
Left 4 cm.
Specimen integrity: Intact
Gross Surface Involvement: Yes
Cut Surface: Right – Unilocular Cystic or Multilocular w/Dominant Cyst
Cystic (50%) and Solid (50%)
Left – Solid (surface)
Gross Necrosis: No Hemorrhage: No
Histologic Type: Epithelial: Invasive
Serous
Architecture Pattern: Solid
Cytologic Atypia: 3
Mitotic grade: 3
Silverberg Grading System: 3
Summary of organs/tissues microscopically involved by tumor: Both ovaries, omentum
peritoneum
Venous/Lymphatic Invasion: Present
Implants (only applies to borderline tumors): NA
Lymph Node Dissection: No
Peritoneal Cytology if Tumor Limited to Ovary: [REDACTED]
Additional Pathologic Findings:
NY ESO-1: Pending
Pathologic Stage: pT2 NX MX

Note: In the left ovary the tumor is limited to the ovarian surface with minimal cortical invasion suggesting that the involvement represents a metastasis rather than a synchronous primary.

[REDACTED]
Pathologist [REDACTED]
[REDACTED]

[page 5 of 5]
ADDENDUM:

The case has been addended to reflect the following:

NYESO-1: Negative
Peritoneal cytology Positive for papillary carcinoma

Pathologic stage: pT3c NX M1

Pathologist

Source: NCI Genomic Data Commons file dd8a545c-6b5e-4cff-ad52-e022ff4f986a (TCGA-59-2355.322BEDF6-E6B5-4275-A186-0075A2EC271E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).